Surgical pathology report (de-identified scan), TCGA case TCGA-AS-3777, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site St. Joseph's Medical Center-(MD), specimen TCGA-AS-3777-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PROCEDURES:

NEPHRECTOMY

CLINICAL HISTORY

OTHER SPECIAL CONSULTATION:

GROSS DESCRIPTION

The specimen is submitted fresh as "left kidney and ureter" and consists of a kidney removed with attached perirenal fat weighing 361 grams with an overall dimension of 19 x 11 x 5 cm. The kidney measures 10 x 6 x 3.5 cm. The segment of attached ureter measures 8 cm in length and 0.6 cm in diameter. There are several segments of vessel at the hilum ranging in length from 0.4 to 1.5 cm in length and measuring up to 2 cm in diameter. The ureteral mucosa is pale tan with the usual striations. The pelvic mucosa is similar in appearance. The renal parenchyma is red brown with normal architecture. There is a 2 x 2.2 x 1.5 cm circumscribed yellow tan tumor adjacent to the renal pelvis which appears to abut upon the renal sinus and approaches to within 0.5 cm of the cortical surface. The calyces are not dilated. The cortex measures up to 0.8 cm in thickness. The capsule strips easily revealing an underlying red brown granular cortical surface. Examination of the attached perirenal fat is unremarkable. The adrenal gland is absent. Representative sections are submitted, multiple (9) labeled as follows:

Cassette 1:	Vessel and ureter margin
Cassettes 2-8:	Tumor
Cassette 9:	Representative uninvolved renal parenchyma

Please note: A portion of tissue is collected for research study.

FINAL DIAGNOSIS

LEFT KIDNEY AND PROXIMAL URETER (NEPHRECTOMY):

- RENAL CELL CARCINOMA, CHROMOPHOBE TYPE (2.2 CM).
- TUMOR IS LIMITED TO THE KIDNEY.
- NO VASCULAR INVASION IS SEEN

[page 2 of 2]
FINAL DIAGNOSIS

(Continued)

- URETERAL AND VASCULAR MARGINS ARE NEGATIVE FOR TUMOR.
- BACKGROUND KIDNEY WITHOUT SIGNIFICANT CHANGES.

COMMENT: THE TUMOR MORPHOLOGY IS CHARACTERISTIC OF THE CHROMOPHOBE TYPE OF RENAL CELL CARCINOMA, AND THE IMMUNOPROFILE FOUND ON THE PRIOR [REDACTED] WAS ALSO SUPPORTIVE OF THIS DIAGNOSIS.

REPORT

SYNOPTIC REPORT: KIDNEY
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: NEPHRECTOMY
LATERALITY: LEFT
TUMOR SITE: CENTRAL/ADJACENT TO PELVIS
TUMOR FOCALITY: UNIFOCAL
TUMOR SIZE: 2.2 CM
MACROSCOPIC EXTENT OF TUMOR: LIMITED TO KIDNEY

HISTOLOGIC TYPE: CHROMOPHOBE RENAL CELL CARCINOMA
HISTOLOGIC GRADE: N/A (FUHRMAN SYSTEM DOES NOT APPLY TO CHROMOPHOBE TYPE OF RENAL CELL CARCINOMA)
VENOUS INVOLVEMENT: NOT SEEN
ADRENAL INVOLVEMENT: N/A - ADRENAL NOT PRESENT

MARGINS:

CAPSULAR/PARENCHYMAL: NEGATIVE
PERINEPHRIC FAT: NEGATIVE
RENAL VEIN: NEGATIVE
URETER: NEGATIVE

LYMPH NODES:

INVOLVED/ # EXAMINED: 0/0

OTHER PERTINENT FINDINGS: NONE

pTNM STAGE: pT1a NX MX (STAGE I)

Source: NCI Genomic Data Commons file 2bb51542-4d58-4f1c-85e7-8eb56a8c0bde (TCGA-AS-3777.DC9BBC26-E6F1-4204-88A5-86124AB150F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).